Gene-level copy-number profile of tumor specimen TCGA-A2-A1G0-01A from TCGA case TCGA-A2-A1G0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 49.3 years (18,002 days).
Specimen TCGA-A2-A1G0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.454e0016-63ac-4727-a1bd-0319b09d17a0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A1G0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3fc07dc1-ab4d-45f9-84f6-5cef9a85c08c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,958; copy number 4: 31,787; copy number 5: 595; copy number 6: 21,957; copy number 8: 2,481; copy number 10: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A1G0-01A-11D-A13J-01): tumor purity 0.51, ploidy 2.44, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 40 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:53,701,692–55,793,960, 40 genes, copy number 10 (within-gene range 6–10): FTO, AC007496.2, AC007496.3, AC007496.1, AC007347.1, AC007347.2, AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1, LINC02140, AC018553.3, AC007343.1, LINC02183, AC007491.1, CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2, MTND5P34, AC109136.1, AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2, AC136621.1, CES1P2, CES1P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
